Somatic mutation profile of tumor specimen 0DR1Z9 from CCDI case PBCFSS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.7 years (5,367 days).
Specimen 0DR1Z9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37bf5c26-7e2c-46a5-bc8d-60f433dcfc70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b728d23-76b1-4469-bc01-c3148959688f

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 2, Intron 2, 3'UTR 2, 5'UTR 2, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 156/505 reads (31%) | hotspot (GDC flag); catalogued as COSV52665429, COSV52669330, COSV52682693, COSV52815283; called by muse, varscan2
- ACSM2B | c.178-1G>T p.X60_splice | Splice Site (SNP) | VAF 75/677 reads (11%) | catalogued as COSV61660406; called by muse, varscan2
- CNTNAP3B | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 264/1316 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs777786556; called by muse, varscan2
- ETFB | c.62G>C p.R21P | Missense Mutation (SNP) | VAF 59/550 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369216610; called by muse, varscan2
- HADHB | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 236/1731 reads (14%) | catalogued as rs552292698; called by muse, varscan2
- MYH11 | c.3856C>A p.Q1286K | Missense Mutation (SNP) | VAF 180/514 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as CM158367; called by muse, varscan2
- PTGDR2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 168/701 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs556535305; called by muse, varscan2
- SPIRE2 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 110/370 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201202825; called by muse, varscan2
- TTK | c.1996G>T p.G666W | Missense Mutation (SNP) | VAF 211/942 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036017, COSV57886460; called by muse, varscan2
- ANKUB1 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 312/1796 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- COL22A1 | c.3847G>C p.D1283H | Missense Mutation (SNP) | VAF 188/1078 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, varscan2
- LCN10 | c.499G>T p.G167W (on ENST00000474369 / NM_001368089.1; = p.G180W on NM_001001712.3) | Missense Mutation (SNP) | VAF 164/484 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, varscan2
- NCOA7 | c.979T>C p.S327P | Missense Mutation (SNP) | VAF 406/1191 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, varscan2
- POPDC3 | c.782G>C p.R261P | Missense Mutation (SNP) | VAF 297/1160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZC3H7B | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 172/496 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- MEGF11 | c.1095C>T p.D365= | Silent (SNP) | VAF 174/702 reads (25%) | catalogued as rs565563572; called by muse, varscan2
- DDX54 | c.*28T>C | 3'UTR (SNP) | VAF 142/553 reads (26%) | called by muse, varscan2
- DIS3L2 | c.2496+17G>T | Intron (SNP) | VAF 114/450 reads (25%) | called by muse, varscan2
- FBXW8 | c.-9G>C | 5'UTR (SNP) | VAF 34/209 reads (16%) | called by muse, varscan2
- MAP2K1 | c.-28A>C | 5'UTR (SNP) | VAF 41/152 reads (27%) | called by muse, varscan2
- TMEM256 | c.118-34C>A | Intron (SNP) | VAF 88/182 reads (48%) | called by muse, varscan2
- TPD52L1 | c.*33G>T | 3'UTR (SNP) | VAF 118/434 reads (27%) | catalogued as rs770018708; called by muse, varscan2
